Gene-level copy-number profile of specimen HCM-SANG-0299-C15-85B-01D-A80T-32 from HCMI case HCM-SANG-0299-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS.
Specimen HCM-SANG-0299-C15-85B-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a4baede6-7551-4b09-95e0-baa124fae8d8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0299-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/fcdeea0f-9a7b-420e-8c89-0e3322b4a724

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,726; copy number 2: 21,480; copy number 3: 23,735; copy number 4: 10,077; copy number 5: 1,465; copy number 6: 315; copy number 9: 4; copy number 10: 7; copy number 11: 2; copy number 13: 65; copy number 19: 8; copy number 23: 2; copy number 24: 3; copy number 35: 3; copy number 113: 17.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 111 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,791,397–12,841,357, 4 genes, copy number 9: PRAMEF1, LINC01784, PRAMEF11, PRAMEF30P.
- chr12:22,609,228–28,978,685, 107 genes, copy number 10–113 (within-gene range 2–113) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,214. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
